Somatic mutation profile of tumor specimen TARGET-30-PASSRS-01A (aliquot TARGET-30-PASSRS-01A-01D) from TARGET case TARGET-30-PASSRS, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 6.8 years (2,492 days).
Specimen TARGET-30-PASSRS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c941e491-5889-45d6-bd45-3da0f118489d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASSRS-10A (Blood Derived Normal), aliquot TARGET-30-PASSRS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a8519a2-1e6c-4acf-9026-652b7e6c9750

The open-access MAF lists 66 somatic variants for this specimen: 50 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Nonsense Mutation 3, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV62427066; called by muse, mutect2, varscan2
- AFF2 | c.3730G>T p.A1244S | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53978749; called by muse, mutect2, varscan2
- ATP6V1H | c.1110C>G p.H370Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62220822; called by muse, mutect2, varscan2
- B4GALNT1 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV57542808; called by mutect2, varscan2
- BMS1 | c.739C>G p.L247V | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65733200, COSV65735772; called by muse, mutect2, varscan2
- CAB39 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs375056331; called by muse, varscan2
- CD177 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.331); catalogued as rs1473587415; called by muse, mutect2
- CNTNAP5 | c.3841G>T p.E1281* | Nonsense Mutation (SNP) | VAF 40/89 reads (45%) | catalogued as COSV70502726, COSV70515864; called by muse, mutect2, varscan2
- CRISP3 | c.545G>T p.G182V (on ENST00000371159 / NM_001368123.1; = p.G164V on NM_006061.4) | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53823805, COSV99539266; called by muse, mutect2, varscan2
- DDX42 | c.2531A>C p.Y844S | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.005); catalogued as COSV63791620; called by muse, mutect2, varscan2
- DGKG | c.2143G>T p.E715* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV53974185; called by muse, mutect2, varscan2
- DNAH9 | c.5540C>T p.P1847L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52380733; called by muse, mutect2, varscan2
- DSPP | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV56807314, COSV99217455; called by muse, mutect2, varscan2
- EXTL3 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.074); catalogued as COSV55040863; called by muse, mutect2, varscan2
- FLG2 | c.2967G>T p.Q989H | Missense Mutation (SNP) | VAF 107/538 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV66174278, COSV66175079; called by muse, mutect2, varscan2
- GBP6 | c.1659G>T p.Q553H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV65012799; called by muse, mutect2
- GUCY2C | c.2225A>C p.E742A | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1441756564, COSV53796584; called by muse, mutect2, varscan2
- HERC1 | c.14196G>C p.E4732D | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV71250683, COSV71250735; called by muse, mutect2, varscan2
- HMCN1 | c.2884G>T p.A962S | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54947581; called by muse, mutect2, varscan2
- HYDIN | c.6374C>G p.T2125S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as rs747843627, COSV59273091; called by mutect2, varscan2
- LPIN2 | c.936G>T p.E312D | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV55245209; called by muse, mutect2, varscan2
- MAT1A | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV64747359; called by muse, mutect2, varscan2
- NDUFB9 | c.214T>C p.W72R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs886513928, COSV52676525; called by muse, mutect2, varscan2
- OR11L1 | c.801G>T p.L267F | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.047); catalogued as COSV63315607; called by muse, mutect2, varscan2
- OR51B4 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV66516817; called by muse, mutect2, varscan2
- PCM1 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as COSV61519472; called by muse, mutect2, varscan2
- PDZD2 | c.4244G>T p.C1415F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); catalogued as rs368527957; called by muse, mutect2, varscan2
- POTEH | c.286A>G p.S96G | Missense Mutation (SNP) | VAF 62/434 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as COSV58887640; called by muse, varscan2
- PXDN | c.2797C>T p.R933C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs780009642, COSV53227347; called by muse, mutect2
- QSOX1 | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV62581824; called by muse, mutect2, varscan2
- RBMXL1 | c.77C>A p.T26K | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV53106472; called by muse, mutect2, varscan2
- SDK1 | c.5970C>A p.S1990R | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV67391284; called by muse, mutect2, varscan2
- SKIV2L | c.308A>G p.Q103R | Missense Mutation (SNP) | VAF 195/540 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.045); catalogued as COSV64814676; called by muse, mutect2, varscan2
- SLC22A6 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.678); catalogued as rs1384537557, COSV64561303; called by muse, mutect2, varscan2
- SPTA1 | c.5054T>A p.V1685E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV63760964; called by muse, mutect2, varscan2
- SSX7 | c.230C>A p.T77K | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.184); catalogued as rs782163035, COSV53341933; called by muse, mutect2, varscan2
- TAS1R1 | c.1177G>A p.V393M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156573230, COSV59841000; called by muse, mutect2, varscan2
- TEX47 | c.264G>T p.L88F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV51880457; called by muse, mutect2, varscan2
- TPP1 | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV55000277; called by muse, mutect2, varscan2
- VPS13D | c.1357G>T p.V453L | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV62535241; called by muse, mutect2, varscan2
- ZNF479 | c.1112A>C p.H371P | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58644466; called by muse, mutect2, varscan2
- ZNF479 | c.671G>T p.C224F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.193); catalogued as rs1554400316, COSV58644478; called by muse, mutect2, varscan2
- ZNF613 | c.690A>T p.K230N (on ENST00000293471 / NM_001031721.4; = p.K194N on NM_024840.4) | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV53274413; called by muse, mutect2, varscan2
- ZNF808 | c.1097C>A p.T366N | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs765754461, COSV63121998; called by muse, mutect2, varscan2
- ACSL1 | c.1298C>A p.T433K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CRLF2 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- IFT122 | c.809G>T p.G270V (on ENST00000348417 / NM_052989.3; = p.G211V on NM_018262.4) | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NAA40 | c.276G>T p.W92C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRAV6 | c.369C>G p.D123E | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TYK2 | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.229); called by muse, mutect2
- ACSL5 | c.222C>A p.A74= (on ENST00000354273; = p.A130= on NM_016234.3) | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as COSV61133948; called by muse, mutect2, varscan2
- ARSJ | c.66A>G p.G22= | Silent (SNP) | VAF 59/271 reads (22%) | catalogued as COSV59540314; called by muse, mutect2, varscan2
- CYP27A1 | c.366C>A p.G122= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs1051087, COSV51470571; ClinVar: benign; called by muse, mutect2, varscan2
- EVC2 | c.939C>T p.T313= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV60404517; called by muse, mutect2, varscan2
- GPR182 | c.735G>T p.L245= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV55627395; called by muse, mutect2, varscan2
- KCNH4 | c.708C>G p.A236= | Silent (SNP) | VAF 31/189 reads (16%) | catalogued as COSV52921630; called by muse, mutect2, varscan2
- MUC16 | c.12477C>G p.S4159= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV67499980; called by muse, mutect2, varscan2
- NMUR2 | c.1026C>T p.I342= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV54917273; called by muse, mutect2
- PHF20 | c.2571G>T p.V857= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV64978265; called by muse, mutect2, varscan2
- PRAMEF10 | c.1179T>C p.A393= | Silent (SNP) | VAF 18/137 reads (13%) | called by muse, varscan2
- SDK1 | c.1098G>T p.L366= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV67391279; called by muse, mutect2, varscan2
- TSGA10IP | c.1173G>A p.E391= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV73245450; called by muse, mutect2, varscan2
- VCAN | c.5259C>A p.P1753= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV54118717; called by muse, mutect2, varscan2
- SNORD116-23 | n.60C>T | RNA (SNP) | VAF 31/154 reads (20%) | called by muse, mutect2, varscan2
- TBX5 | c.982+29C>G | Intron (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- TTN | c.34265-4914C>A | Intron (SNP) | VAF 69/225 reads (31%) | catalogued as rs370418622, COSV60398425; called by muse, mutect2, varscan2
